Somatic mutation profile of tumor specimen TCGA-19-2624-01A (aliquot TCGA-19-2624-01A-01D-1495-08) from TCGA case TCGA-19-2624, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.7 years (18,891 days).
Specimen TCGA-19-2624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cab19f2-b19e-424b-97a5-de2025f6972c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2624-10A (Blood Derived Normal), aliquot TCGA-19-2624-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0240d7a1-a06c-4647-879f-1441b64b4dd3

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 2, Intron 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.10887G>T p.K3629N | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV60915103, COSV60932290; called by muse, mutect2
- AL121899.2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1205086132, COSV67352495; called by muse, mutect2, varscan2
- ALPP | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs781682267, COSV67398312; called by muse, mutect2, varscan2
- ATXN2 | c.3478C>T p.Q1160* (on ENST00000550104; = p.Q1000* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as COSV66482503; called by muse, mutect2, varscan2
- CBFA2T3 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs774310781, COSV51922943, COSV51929210; called by muse, mutect2, varscan2
- CSDE1 | c.1310C>G p.T437S (on ENST00000358528 / NM_001007553.3; = p.T406S on NM_007158.6) | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.026); catalogued as COSV54743507, COSV99795359; called by muse, mutect2, varscan2
- CYP46A1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381511659, COSV55893974; called by muse, mutect2, varscan2
- EGFR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 162/4075 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51775191, COSV51835541; called by muse, mutect2
- EGFR | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 164/4066 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV51865283; called by muse, mutect2
- F11R | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs144844671, COSV57036882; called by muse, mutect2, varscan2
- FOXJ2 | c.1270A>G p.S424G | Missense Mutation (SNP) | VAF 135/325 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50818062; called by muse, mutect2, varscan2
- FZD10 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs1566096577, COSV57472117; called by muse, mutect2, varscan2
- KCTD18 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs763515598, COSV63344131; called by muse, mutect2, varscan2
- KRTAP6-1 | c.169T>A p.C57S | Missense Mutation (SNP) | VAF 31/155 reads (20%) | PolyPhen benign (0.031); catalogued as COSV58169020; called by muse, mutect2, varscan2
- LHFPL3 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67821335; called by muse, mutect2, varscan2
- MAGEB18 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV57463701; called by muse, mutect2, varscan2
- MYH9 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs569649580, COSV53393946; called by muse, mutect2, varscan2
- NMUR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs756384094, COSV54918385; called by muse, mutect2, varscan2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2, varscan2
- OR52N4 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs574734485, COSV57890742; called by muse, mutect2, varscan2
- OR8I2 | c.516C>A p.S172R | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56167382, COSV56171043; called by muse, mutect2, varscan2
- PLCXD3 | c.839T>A p.V280D | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV60607400; called by muse, mutect2, varscan2
- SEMG1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs770232552, COSV54872445; called by muse, mutect2, varscan2
- ST14 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1242315506, COSV53837357; called by muse, mutect2, varscan2
- STEAP1 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.312); catalogued as COSV51883174; called by muse, mutect2, varscan2
- TBC1D10C | c.1281del p.I428Sfs*126 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs756043635; called by mutect2, pindel, varscan2
- TMEM241 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs778244273, COSV67242728; called by muse, mutect2, varscan2
- GPR179 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TMEM161B | c.617_620del p.D206Vfs*11 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.3399C>T p.V1133= | Silent (SNP) | VAF 172/391 reads (44%) | catalogued as rs753134176, COSV60932296; called by muse, mutect2, varscan2
- ALDH18A1 | c.552T>A p.A184= | Silent (SNP) | VAF 36/50 reads (72%) | catalogued as COSV64662421; called by muse, mutect2, varscan2
- ESPL1 | c.216G>A p.G72= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as rs1239419058, COSV57758664; called by muse, mutect2, varscan2
- LMNTD2 | c.129C>T p.P43= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs1332427442, COSV54248023; called by muse, mutect2, varscan2
- LRRC25 | c.675C>T p.S225= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- NEDD1 | c.1899G>A p.L633= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs772224446, COSV57142642; called by muse, mutect2, varscan2
- PARD3B | c.924T>C p.G308= | Silent (SNP) | VAF 63/152 reads (41%) | catalogued as COSV62507890; called by muse, mutect2, varscan2
- VNN1 | c.1293C>T p.F431= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs769909618, COSV63389661; called by muse, mutect2, varscan2
- ZC3H11A | c.1746G>A p.R582= | Silent (SNP) | VAF 68/135 reads (50%) | catalogued as COSV59745584; called by muse, mutect2, varscan2
- GABRG2 | c.1249-1356G>A | Intron (SNP) | VAF 58/154 reads (38%) | catalogued as rs755430911, COSV62716923; called by muse, mutect2, varscan2
- LINC01600 | n.995C>G | RNA (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- TAC3 | c.292+87G>A | Intron (SNP) | VAF 37/51 reads (73%) | catalogued as rs767638274; called by muse, mutect2, varscan2
